CCDI case PBBYUF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7105b64a-5d19-429e-a8fd-4b3e46908924

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,283 days).

Biospecimens (3 samples)
- Sample 0DKWN3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DKWNE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DKWNQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
